Somatic mutation profile of tumor specimen TCGA-CV-7252-01A (aliquot TCGA-CV-7252-01A-11D-2012-08) from TCGA case TCGA-CV-7252, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.8 years (22,934 days).
Specimen TCGA-CV-7252-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95f8a0e5-68e5-45c2-bf17-4a9bb1b1c8ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7252-10A (Blood Derived Normal), aliquot TCGA-CV-7252-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7743bc37-1b63-4f27-a476-c3353b0c60f9

The open-access MAF lists 246 somatic variants for this specimen: 175 protein-altering or splice-affecting, 64 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 64, Nonsense Mutation 16, Frame Shift Del 5, Frame Shift Ins 4, In Frame Del 3, Intron 3, 3'UTR 2, RNA 2, Splice Site 2, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4070G>A p.G1357E | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771609901, COSV100228711; called by muse, mutect2, varscan2
- ABHD16B | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1385474005, COSV99410609; called by muse, mutect2, varscan2
- ABHD17B | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100330161; called by muse, mutect2
- ABR | c.1306-1G>A p.X436_splice (on ENST00000302538 / NM_021962.5; = p.X399_splice on NM_001092.5) | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99347715; called by muse, mutect2, varscan2
- ACTC1 | c.1074G>C p.W358C | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51761459, COSV99291727; called by muse, mutect2, varscan2
- ACVR1B | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV57777110; called by muse, mutect2, varscan2
- ADAMTS20 | c.4663C>T p.R1555* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as rs747087971, COSV67141288; called by mutect2, varscan2
- ADRB3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1484789579, COSV100799820; called by muse, mutect2, varscan2
- AIFM3 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.087); catalogued as rs765401131, COSV53146643; called by muse, mutect2, varscan2
- AKT2 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV100251512; called by muse, mutect2, varscan2
- ALX1 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV100374342; called by muse, mutect2, varscan2
- ANKRD13A | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV99923883; called by muse, mutect2, varscan2
- AOC3 | c.1649C>A p.A550D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV99520074; called by muse, mutect2, varscan2
- APLP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149975560, COSV53840570; called by muse, mutect2, varscan2
- ARC | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV100751685; called by muse, mutect2
- ARID2 | c.3733C>T p.Q1245* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100535820; called by muse, mutect2, varscan2
- ATG4A | c.340A>C p.I114L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1569309112, COSV100619655; called by muse, mutect2, varscan2
- ATP6V0B | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.047); catalogued as COSV52545284; called by muse, mutect2, varscan2
- ATRX | c.2769G>T p.K923N | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100970424; called by muse, mutect2, varscan2
- BACH2 | c.1594G>C p.G532R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99998768, COSV99999774; called by muse, mutect2, varscan2
- BBS9 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99627223; called by muse, mutect2, varscan2
- BTN2A2 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.454); catalogued as COSV100760324; called by muse, mutect2, varscan2
- C11orf87 | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100535725; called by muse, mutect2, varscan2
- CATSPER2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.148); catalogued as COSV100390653; called by muse, mutect2, varscan2
- CATSPERD | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs757837954, COSV101062597, COSV67534240; called by muse, mutect2, varscan2
- CD209 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as rs906890103, COSV99213825; called by muse, mutect2, varscan2
- CEMIP | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs372603353; called by muse, mutect2, varscan2
- CEP135 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99954278; called by muse, mutect2, varscan2
- CHD6 | c.5587C>T p.H1863Y | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); catalogued as rs1368672240, COSV100950811; called by muse, mutect2, varscan2
- CLDN10 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100176095; called by muse, mutect2, varscan2
- CMC4 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 36/197 reads (18%) | catalogued as COSV100749876; called by muse, mutect2, varscan2
- CNBD2 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100839067; called by muse, mutect2, varscan2
- COL14A1 | c.2816G>A p.W939* | Nonsense Mutation (SNP) | VAF 37/139 reads (27%) | catalogued as COSV99918623; called by muse, mutect2, varscan2
- CPB2 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99473026; called by muse, mutect2, varscan2
- CPD | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV56716787, COSV99852669; called by muse, mutect2
- CRB1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100957765; called by muse, mutect2, varscan2
- CSGALNACT1 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs751594554, COSV100174745; called by muse, mutect2, varscan2
- CST1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs778452912, COSV100494321; called by muse, mutect2, varscan2
- CTH | c.1017G>C p.E339D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100697054; called by muse, mutect2, varscan2
- CUX1 | c.44C>A p.A15D (on ENST00000292535 / NM_181552.4; = p.A26D on NM_001913.5) | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52904453, COSV99471013; called by muse, mutect2, varscan2
- DDB1 | c.1233G>A p.W411* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as COSV100074457; called by muse, mutect2, varscan2
- DGKD | c.1279C>T p.Q427* (on ENST00000264057 / NM_152879.3; = p.Q383* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV99895905; called by muse, mutect2, varscan2
- DLGAP4 | c.1444del p.A482Pfs*73 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as COSV59422901; called by mutect2, pindel
- DPY19L2 | c.1983C>A p.Y661* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV100193099, COSV100193344; called by muse, mutect2, varscan2
- DVL1 | c.1571C>T p.P524L (on ENST00000378888 / NM_001330311.2; = p.P499L on NM_004421.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs551168455, COSV100229386; called by muse, mutect2, varscan2
- EBNA1BP2 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777466628, COSV99355888; called by muse, mutect2, varscan2
- EFHC1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs796052412, COSV100931971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMILIN2 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs749295130, COSV54421846; called by muse, mutect2, varscan2
- ENTPD7 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs187682149; called by muse, mutect2, varscan2
- EPHA2 | c.2561G>A p.W854* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100626057; called by muse, mutect2, varscan2
- EVA1A | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV99285435; called by muse, mutect2, varscan2
- EZH2 | c.1069C>T p.R357W (on ENST00000460911 / NM_001203247.2; = p.R362W on NM_004456.5) | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1193491117, COSV100235282; called by muse, mutect2, varscan2
- F2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV61315536; called by muse, mutect2, varscan2
- FADS2 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608557; called by muse, mutect2, varscan2
- FSCB | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV61219215; called by muse, mutect2, varscan2
- GABRA4 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs767732000, COSV51922862; called by muse, mutect2, varscan2
- GBP5 | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV58592360; called by muse, mutect2, varscan2
- GPAM | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100788146; called by muse, varscan2
- GPIHBP1 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100427339; called by muse, mutect2, varscan2
- GPR37L1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765614906, COSV100938530; called by muse, mutect2, varscan2
- GSAP | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs6950836, COSV99990077; called by muse, mutect2, varscan2
- GUCY2F | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54304196, COSV99484740; called by muse, mutect2, varscan2
- GUSB | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59222651; called by muse, mutect2, varscan2
- HADHB | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100501941; called by muse, mutect2, varscan2
- HDAC4 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100613063; called by muse, mutect2, varscan2
- HFM1 | c.987G>T p.L329F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.199); catalogued as COSV99645744; called by muse, mutect2, varscan2
- HPS6 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs140222296, COSV54625394; called by muse, mutect2, varscan2
- IGSF10 | c.7502G>C p.R2501T | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV56374006, COSV56375996; called by muse, mutect2, varscan2
- IRF1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV55378884; called by muse, mutect2, varscan2
- IRF1 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV99810459; called by muse, varscan2
- ITGB1 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as rs373574635; called by mutect2, varscan2
- ITGB1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.043); catalogued as COSV100171452; called by muse, mutect2, varscan2
- JMJD8 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as rs778481377, COSV50197729; called by muse, mutect2, varscan2
- KAT5 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs1255110429, COSV100383869; called by muse, mutect2, varscan2
- KCNJ4 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.606); catalogued as COSV57856618; called by muse, mutect2, varscan2
- KCNT2 | c.1922T>C p.I641T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV99652633; called by muse, mutect2, varscan2
- KCTD4 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100476709; called by muse, mutect2, varscan2
- KDF1 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100264431; called by muse, mutect2, varscan2
- KDM7A | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs199627366, COSV99134156; called by muse, mutect2, varscan2
- KHDC4 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as COSV100850782; called by muse, mutect2, varscan2
- KIF17 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928806; called by muse, mutect2, varscan2
- KIF21B | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as rs757271782, COSV59760963; called by muse, mutect2, varscan2
- KLC1 | c.1312-1G>A p.X438_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99871376; called by muse, mutect2, varscan2
- KMT2D | c.15700G>A p.E5234K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV56459692, COSV56503806; called by muse, mutect2, varscan2
- L1CAM | c.3715G>A p.G1239R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100648981; called by muse, mutect2, varscan2
- LAMA4 | c.866T>C p.L289P (on ENST00000230538 / NM_001105206.3; = p.L282P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.857); catalogued as COSV100037999; called by muse, mutect2, varscan2
- LAMC2 | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 107/376 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.23); catalogued as COSV99917285; called by muse, mutect2, varscan2
- LARP6 | c.1413G>T p.L471F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100150780; called by muse, mutect2, varscan2
- LIPI | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100753580; called by muse, mutect2, varscan2
- LRIT3 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100015984; called by muse, mutect2, varscan2
- LRP6 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 34/130 reads (26%) | catalogued as COSV53785999, COSV99742839; called by muse, mutect2, varscan2
- LRRC4 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974842; called by muse, varscan2
- LRRTM3 | c.1136C>A p.T379K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as COSV100791565; called by muse, mutect2, varscan2
- LY9 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as rs12049314, COSV54435069; called by muse, mutect2, varscan2
- MAP1A | c.5519C>A p.A1840D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV100288388; called by muse, mutect2, varscan2
- MAP2 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV104389275, COSV99559010; called by muse, mutect2, varscan2
- MAP4K3 | c.2009A>G p.K670R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as COSV99810193; called by muse, mutect2, varscan2
- MLKL | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100087265; called by muse, mutect2
- MUC16 | c.25451C>T p.S8484F | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as rs780878857, COSV101199220; called by muse, mutect2, varscan2
- MYH4 | c.5299G>T p.A1767S | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.764); catalogued as rs960560117, COSV99700809; called by muse, mutect2, varscan2
- NCOR1 | c.5752G>C p.E1918Q | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99248896; called by muse, mutect2, varscan2
- NFATC4 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99145008; called by muse, mutect2, varscan2
- NOL10 | c.1819T>A p.S607T | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100629985; called by muse, mutect2, varscan2
- NOVA2 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99611282; called by muse, mutect2, varscan2
- NSFL1C | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs201890755, COSV53792894, COSV99401474; called by muse, mutect2, varscan2
- NT5C1A | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV99348354; called by muse, mutect2, varscan2
- OR2L2 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV100823361, COSV63548280; called by muse, mutect2, varscan2
- OR5L2 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV65723801, COSV65724108; called by muse, mutect2, varscan2
- OR5M11 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101602029; called by muse, mutect2, varscan2
- OR5M8 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100510579, COSV100510613; called by muse, mutect2
- OSMR | c.2518C>T p.L840F | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as COSV57093168, COSV99952944; called by muse, mutect2, varscan2
- PACS2 | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100330675; called by muse, mutect2, varscan2
- PAMR1 | c.1574G>A p.G525E (on ENST00000619888 / NM_001001991.3; = p.G542E on NM_015430.4) | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53515182, COSV53517357; called by muse, mutect2, varscan2
- PCDH12 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99186818; called by muse, mutect2, varscan2
- PDAP1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.292); catalogued as COSV63299142; called by muse, varscan2
- PDZD2 | c.4666G>A p.E1556K | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99224453; called by muse, mutect2, varscan2
- PLA2R1 | c.2595G>A p.A865= | Splice Region (SNP) | VAF 29/74 reads (39%) | catalogued as rs543739690, COSV99322605; called by muse, mutect2, varscan2
- PRG3 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs1374502643, COSV99755864; called by muse, mutect2, varscan2
- PSME3 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.174); catalogued as COSV99513571; called by muse, mutect2
- PTPRC | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.298); catalogued as COSV100722372; called by muse, mutect2, varscan2
- RAI1 | c.4727G>A p.R1576H | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs764594243, COSV99883725; called by muse, mutect2, varscan2
- ROS1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs867987684, COSV63856119; called by muse, mutect2, varscan2
- RSPH4A | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV99994059; called by muse, mutect2, varscan2
- RTL5 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.754); catalogued as COSV101029973; called by muse, mutect2, varscan2
- RXRB | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100553699; called by muse, mutect2, varscan2
- RYR3 | c.10406C>T p.S3469F (on ENST00000389232; = p.S3470F on NM_001036.6) | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101212383; called by muse, mutect2, varscan2
- SIRPA | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100605108; called by muse, mutect2, varscan2
- SLC17A9 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV100947779; called by muse, mutect2, varscan2
- SLC8A3 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | catalogued as COSV100776061; called by muse, varscan2
- SLF2 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV99488848; called by muse, mutect2, varscan2
- SMC4 | c.1497G>A p.M499I | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV100644002; called by muse, mutect2, varscan2
- SPATA25 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 46/235 reads (20%) | catalogued as COSV99509762; called by muse, mutect2, varscan2
- SRD5A2 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV99252318; called by muse, mutect2, varscan2
- SULT1C3 | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61255038; called by muse, mutect2, varscan2
- TACR3 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100510297; called by muse, mutect2, varscan2
- TESPA1 | c.926G>A p.R309K (on ENST00000316577 / NM_001098815.3; = p.R171K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100345093; called by muse, mutect2, varscan2
- TET3 | c.4768G>A p.E1590K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.093); catalogued as rs777199933, COSV101327722; called by muse, mutect2, varscan2
- TFE3 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV59949003; called by muse, mutect2, varscan2
- TGFBR2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV55448334; called by muse, mutect2, varscan2
- THOC2 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV55548697, COSV55556863; called by muse, mutect2, varscan2
- THRA | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs775052494, COSV99225406; called by muse, mutect2, varscan2
- TLR6 | c.2167C>G p.L723V | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV101126255, COSV67935438; called by muse, mutect2, varscan2
- TMC3 | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100845875; called by muse, mutect2, varscan2
- TMC4 | c.1738C>T p.R580C (on ENST00000617472 / NM_001145303.3; = p.R574C on NM_144686.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1295620148, COSV55827787, COSV55828069; called by muse, mutect2, varscan2
- TOX3 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs776924792, COSV99567314; called by muse, mutect2, varscan2
- TP53 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 71/273 reads (26%) | catalogued as COSV52734084, COSV53134595; called by muse, mutect2, varscan2
- TRIML1 | c.1028G>T p.W343L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100205854; called by muse, mutect2, varscan2
- TRIP11 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as rs1170300809, COSV99970504; called by muse, mutect2, varscan2
- TTC37 | c.3653G>A p.G1218E | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1402654631, COSV100706488; called by muse, mutect2, varscan2
- UBR3 | c.4922C>T p.S1641F | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV99773721; called by muse, mutect2, varscan2
- UNC13C | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99514459; called by muse, mutect2, varscan2
- UNC5A | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as rs754389756, COSV52839778; called by muse, mutect2, varscan2
- VSIR | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99820006; called by muse, mutect2, varscan2
- WDR44 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.985); catalogued as COSV99561410; called by muse, mutect2, varscan2
- ZBED9 | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV71729263; called by muse, mutect2
- ZNF211 | c.1021T>C p.Y341H (on ENST00000347302 / NM_198855.4; = p.Y354H on NM_006385.5) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99560172; called by muse, mutect2, varscan2
- ZNF224 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs770851179, COSV61241667; called by muse, mutect2, varscan2
- ZNF391 | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99772519; called by muse, mutect2, varscan2
- ZNF442 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as rs1161484317, COSV54423735, COSV99664299; called by muse, mutect2, varscan2
- ZNF48 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs369371622, COSV60782647; called by muse, mutect2, varscan2
- ZXDB | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100885854; called by muse, varscan2
- ARGLU1 | c.313_315dup p.E105dup | In Frame Ins (INS) | VAF 18/88 reads (20%) | called by mutect2, varscan2
- ARID2 | c.159_160del p.R53Sfs*12 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by pindel, varscan2
- CASP8 | c.814_819del p.T272_T273del (on ENST00000432109 / NM_033355.3; = p.T289_T290del on NM_001228.4) | In Frame Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- EPHA2 | c.535dup p.Y179Lfs*35 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- FAT1 | c.9259dup p.R3087Pfs*2 | Frame Shift Ins (INS) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- FAT1 | c.8271_8283del p.G2758Wfs*32 | Frame Shift Del (DEL) | VAF 48/212 reads (23%) | called by mutect2, pindel, varscan2
- GART | c.55_101del p.W19Rfs*9 | Frame Shift Del (DEL) | VAF 24/161 reads (15%) | called by mutect2, pindel, varscan2*
- GMIP | c.2155_2166del p.L719_P722del | In Frame Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- KDF1 | c.89_90del p.Y30* | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by pindel, varscan2
- KMT2B | c.4241_4261del p.R1414_L1420del | In Frame Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, varscan2
- KMT2D | c.15074_15077dup p.R5027Tfs*12 | Frame Shift Ins (INS) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- TP53 | c.580_581dup p.I195Lfs*53 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- ULK1 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKT1S1 | c.474G>A p.E158= (on ENST00000344175 / NM_001098633.4; = p.E178= on NM_032375.5) | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV100465071; called by muse, mutect2, varscan2
- ALDH1A3 | c.1242G>T p.G414= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100320311; called by muse, varscan2
- ANKS4B | c.1176G>A p.R392= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV100289768; called by muse, mutect2, varscan2
- AWAT1 | c.510C>A p.G170= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV100997191; called by muse, mutect2, varscan2
- BET1L | c.300C>T p.F100= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs905466815, COSV57315001; called by muse, mutect2, varscan2
- CATSPER1 | c.1965C>T p.I655= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100375793, COSV56409857; called by muse, mutect2, varscan2
- CDH23 | c.4950C>T p.L1650= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99820008; called by muse, mutect2, varscan2
- CDH3 | c.1701C>T p.I567= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs140790125; called by muse, mutect2, varscan2
- CELSR2 | c.6930G>A p.E2310= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99603473; called by muse, mutect2, varscan2
- CLVS2 | c.507C>T p.F169= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV51562595, COSV51566926; called by muse, mutect2, varscan2
- CNTNAP2 | c.3921G>A p.A1307= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs750224036, COSV100664599; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTTNBP2 | c.3756C>T p.A1252= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99353545; called by muse, mutect2, varscan2
- DENND5B | c.1197T>A p.V399= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100171177; called by muse, mutect2, varscan2
- DISP3 | c.1923G>T p.L641= | Silent (SNP) | VAF 57/222 reads (26%) | catalogued as COSV99608017; called by muse, mutect2, varscan2
- DOCK7 | c.5100A>G p.E1700= (on ENST00000635253 / NM_001367561.1; = p.E1669= on NM_033407.3) | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs752930988, COSV99223760; called by muse, mutect2, varscan2
- ENPP4 | c.723C>T p.T241= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs1324850509, COSV100320272; called by muse, mutect2, varscan2
- FAXDC2 | c.234C>T p.L78= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100394193; called by muse, mutect2, varscan2
- FYB2 | c.1494G>A p.R498= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV100599412; called by muse, mutect2, varscan2
- GIGYF1 | c.2673G>A p.L891= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99309098; called by muse, mutect2, varscan2
- GNB2 | c.834C>T p.F278= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV99309096; called by muse, mutect2, varscan2
- GPR25 | c.135C>G p.L45= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100421706, COSV58499031; called by muse, mutect2, varscan2
- HOXC11 | c.342C>A p.L114= | Silent (SNP) | VAF 58/265 reads (22%) | catalogued as COSV99678377; called by muse, mutect2, varscan2
- JRK | c.1329G>A p.A443= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs376782719; called by muse, mutect2
- KCNMB1 | c.534G>A p.V178= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV99210665; called by muse, mutect2, varscan2
- KDM2B | c.1542G>A p.L514= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100997340; called by muse, mutect2, varscan2
- LAMC3 | c.2079G>A p.R693= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100735930; called by muse, mutect2, varscan2
- LRRC4 | c.732C>G p.L244= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV50818034, COSV99974840; called by muse, mutect2, varscan2
- LRRC4 | c.501C>T p.F167= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV99974845; called by muse, varscan2
- LTN1 | c.3618C>T p.F1206= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV100797933; called by muse, mutect2, varscan2
- MAOB | c.834G>T p.L278= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV100955981; called by muse, mutect2, varscan2
- MAP3K10 | c.717C>T p.L239= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs377562938; called by muse, mutect2, varscan2
- MAP3K21 | c.1026C>T p.V342= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100786249; called by muse, varscan2
- MATN2 | c.1980C>T p.I660= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs763374430, COSV54708650, COSV54710523; called by muse, mutect2, varscan2
- METTL24 | c.798C>T p.L266= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100133230; called by muse, mutect2, varscan2
- MUC5AC | c.13929C>T p.S4643= | Silent (SNP) | VAF 50/147 reads (34%) | catalogued as rs756998712, COSV100611388; called by muse, mutect2, varscan2
- MXD3 | c.552C>T p.A184= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs371715811; called by muse, mutect2, varscan2
- MYO3A | c.1531C>T p.L511= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs1335980755, COSV99779068, COSV99780341; called by muse, mutect2, varscan2
- NEUROD2 | c.1134G>T p.A378= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs773848127, COSV100223111; called by muse, mutect2, varscan2
- NFKBIA | c.309C>T p.F103= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs912149799, COSV99395032; called by muse, mutect2, varscan2
- NHS | c.2484G>A p.P828= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as rs781782408, COSV66276760; called by muse, mutect2, varscan2
- NUTM1 | c.2853G>A p.E951= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100148934; called by muse, mutect2, varscan2
- OBSCN | c.8082C>T p.F2694= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as COSV99475647; called by muse, mutect2, varscan2
- OCM2 | c.111C>T p.S37= | Silent (SNP) | VAF 45/183 reads (25%) | catalogued as COSV99990781; called by muse, mutect2, varscan2
- PACSIN1 | c.238C>T p.L80= | Silent (SNP) | VAF 39/181 reads (22%) | catalogued as COSV99762963; called by muse, mutect2, varscan2
- PCK2 | c.60C>A p.G20= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV99394241; called by muse, mutect2, varscan2
- PDE8B | c.942C>T p.L314= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs749726483, COSV99366520; called by muse, mutect2, varscan2
- PIAS4 | c.1233G>A p.K411= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99518718; called by mutect2, varscan2
- PKHD1 | c.1641C>T p.C547= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV100582305; called by muse, mutect2, varscan2
- PRCC | c.648G>A p.K216= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV99618565; called by muse, mutect2, varscan2
- PTK2B | c.942G>A p.E314= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100593668; called by muse, mutect2, varscan2
- SALL1 | c.3639C>T p.F1213= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV51764269; called by muse, mutect2, varscan2
- SERPINA4 | c.1152G>A p.A384= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs769083861, COSV54068687, COSV54071277; called by muse, mutect2, varscan2
- SH2D4A | c.939A>G p.T313= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99744453; called by muse, mutect2, varscan2
- SHANK1 | c.2037G>A p.R679= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV99520717; called by muse, mutect2, varscan2
- SLC45A3 | c.1152C>T p.L384= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs758201803, COSV100901111; called by muse, mutect2, varscan2
- SMYD4 | c.600A>G p.E200= | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as COSV100562987; called by muse, mutect2, varscan2
- SRPX | c.1317C>T p.F439= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100655994; called by muse, mutect2, varscan2
- STK33 | c.678A>T p.I226= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs775357872, COSV100173860; called by muse, mutect2, varscan2
- STUB1 | c.879C>T p.F293= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV99555550; called by muse, mutect2, varscan2
- TMEM159 | c.162C>T p.T54= | Silent (SNP) | VAF 41/170 reads (24%) | catalogued as COSV99238603; called by muse, mutect2, varscan2
- XAF1 | c.429A>G p.R143= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100695005; called by muse, mutect2, varscan2
- ZBTB40 | c.240G>A p.T80= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs138737436; called by muse, mutect2, varscan2
- ZFC3H1 | c.5670G>C p.L1890= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV101110431; called by muse, mutect2, varscan2
- ZSWIM4 | c.1233G>A p.G411= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV99584674; called by muse, mutect2, varscan2
- ADGRG6 | c.*41G>C | 3'UTR (SNP) | VAF 53/225 reads (24%) | catalogued as COSV99746572; called by muse, mutect2, varscan2
- AGAP7P | n.1098A>G | RNA (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2522-3528G>C | Intron (SNP) | VAF 33/137 reads (24%) | catalogued as COSV99430700; called by muse, mutect2, varscan2
- FAM86C1P | n.177C>A | RNA (SNP) | VAF 21/104 reads (20%) | catalogued as rs1432291461, COSV100660642; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4805G>T | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as rs1383926569, COSV61087733; called by muse, mutect2, varscan2
- PPM1M | c.*292C>G | 3'UTR (SNP) | VAF 8/33 reads (24%) | catalogued as COSV56599496; called by muse, mutect2, varscan2
- UNC119 | c.610+30G>A | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs773884232, COSV99971655; called by muse, mutect2, varscan2
